Somatic mutation profile of tumor specimen C3N-00734-01 (aliquot CPT0026030010) from CPTAC case C3N-00734, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 53.1 years (19,402 days).
Specimen C3N-00734-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01ffd6b0-7268-4031-8422-f21875f36343.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00734-31 (Blood Derived Normal), aliquot CPT0028500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fff38182-c1ee-45db-8e3b-e7fba91e76c4

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 3, Intron 3, In Frame Del 2, Frame Shift Ins 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1647T>G p.N549K | Missense Mutation (SNP) | VAF 171/331 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BUD23 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334787119, COSV56096154; called by muse, mutect2, varscan2
- CACNA1B | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs754208034, COSV53113810; called by muse, mutect2, varscan2
- CCDC47 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.176); catalogued as rs747056842; called by muse, mutect2, varscan2
- CMTM6 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs760984074; called by muse, mutect2, varscan2
- CTC1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs750352024; called by muse, varscan2
- CYP2F1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs749467843; called by muse, mutect2, varscan2
- FGD2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs750902984; called by muse, mutect2, varscan2
- FGD5 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.368); catalogued as rs1000136442; called by muse, mutect2, varscan2
- INSYN2A | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs372715738; called by muse, mutect2, varscan2
- LYPD3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1029422256; called by muse, mutect2, varscan2
- SPATA48 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs139200555; called by muse, mutect2, varscan2
- UBP1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV52144862; called by muse, mutect2, varscan2
- ARID1A | c.1650del p.Y551Tfs*68 | Frame Shift Del (DEL) | VAF 62/222 reads (28%) | called by mutect2, varscan2
- ARMCX5-GPRASP2 | c.826_827del p.Q276Afs*4 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by pindel, varscan2
- B4GALNT4 | c.1441C>A p.R481S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBR4 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRM2 | c.1025C>G p.T342S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EIF4H | c.123dup p.Y42Lfs*22 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- FBXO24 | c.1291G>A p.E431K (on ENST00000241071 / NM_033506.3; = p.E469K on NM_012172.5) | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PIK3R1 | c.1142_1144del p.I381del (on ENST00000521381 / NM_181523.3; = p.I111del on NM_181504.4) | In Frame Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- PTEN | c.400dup p.M134Nfs*46 | Frame Shift Ins (INS) | VAF 146/361 reads (40%) | called by mutect2, pindel, varscan2
- RIN2 | c.1313A>T p.E438V (on ENST00000255006 / NM_001242581.1; = p.E389V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF8 | c.850_853del p.K284Lfs*29 | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | called by pindel, varscan2
- SIRPD | c.73+1G>A p.X25_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | called by muse, varscan2
- SMC3 | c.2761_2763del p.E921del | In Frame Del (DEL) | VAF 110/218 reads (50%) | called by mutect2, pindel, varscan2
- TLR9 | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ADAMTS5 | c.480C>T p.H160= | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- ANK2 | c.5787G>A p.S1929= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs145614759; called by muse, mutect2, varscan2
- BTG3 | c.711T>C p.H237= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as rs752906772; called by muse, mutect2, varscan2
- MACF1 | c.14808C>T p.V4936= (on ENST00000372915; = p.V2869= on NM_012090.5) | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV57138902; called by muse, mutect2, varscan2
- NLGN4X | c.2043C>T p.V681= | Silent (SNP) | VAF 100/360 reads (28%) | catalogued as rs770117821, COSV52005134, COSV52039876; called by muse, mutect2, varscan2
- VPS4B | c.405C>T p.D135= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs778360477; called by muse, mutect2, varscan2
- ZFHX4 | c.2259C>T p.C753= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as rs746206492, COSV51507602, COSV99265249; called by muse, mutect2, varscan2
- AHCYL2 | c.364-2085G>C | Intron (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- CCDC74B | c.296-71G>A | Intron (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- KCNE2 | c.-12-25G>A | Intron (SNP) | VAF 35/131 reads (27%) | catalogued as rs775710105; called by muse, mutect2, varscan2
- SLC11A2 | c.*1737G>A | 3'UTR (SNP) | VAF 27/113 reads (24%) | catalogued as rs1204527545; called by muse, mutect2, varscan2
